Gene-level copy-number profile of tumor specimen TCGA-BQ-7048-01A from TCGA case TCGA-BQ-7048, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 64.2 years (23,460 days).
Specimen TCGA-BQ-7048-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.b401eca4-aeb5-4b20-9f1b-240a513b68c2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BQ-7048-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9cdf9cc8-ca1b-4ec9-8013-b34d28e699fd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 5,098; copy number 3: 24; copy number 4: 54,132; copy number 5: 134; copy number 6: 2; copy number 7: 39; copy number 8: 3; copy number 10: 24; copy number 11: 3; copy number 12: 53; copy number 18: 106; copy number 20: 85; copy number 22: 25; copy number 24: 28; copy number 32: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BQ-7048-01A-11D-1959-01): tumor purity 0.8, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 387 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:37,091,314–48,068,689, 254 genes, copy number 12–32 (within-gene range 7–32) (broad region; genes not listed).
- chr6:50,857,255–50,913,256, 3 genes, copy number 11: RPS17P5, AL049693.1, FTH1P5.
- chr19:32,830,509–35,717,038, 130 genes, copy number 10–18 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
